CCG case CUPP-B391 — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3bfc0483-d13c-4512-a028-c469a05482b7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Year of birth: 1959; Vital status: Alive.

Diagnoses (4)
1. Carcinoma, metastatic, NOS (the primary disease): ICD-O-3 morphology code: 8020/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 57.3 years (20,942 days); Year of diagnosis: 2017; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: TX; AJCC clinical M: M1a; AJCC clinical stage: Stage IIIA; AJCC pathologic T: TX; AJCC pathologic M: M1a; AJCC pathologic stage: Stage IIIA; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes tested: 1; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Timepoint category: First Treatment.
2. Progression of the lung (histology not recorded by GDC). Age at diagnosis: 58.0 years (21,180 days); Year of diagnosis: 2017; Days to diagnosis: 238 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.
3. Progression of the lymph node (histology not recorded by GDC). Age at diagnosis: 58.0 years (21,180 days); Year of diagnosis: 2017; Days to diagnosis: 238 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.
4. Progression of the connective, subcutaneous and other soft tissues (histology not recorded by GDC). Age at diagnosis: 58.0 years (21,180 days); Year of diagnosis: 2017; Days to diagnosis: 238 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.

Follow-up (5 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 100; ECOG performance status: 0.
- Day 238 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues, NOS; Days to progression: 238 days.
- Day 238 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 238 days.
- Day 238 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 238 days.
- Days to follow up: 614 days (1.7 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 87 kg; Height: 186 cm; BMI: 25.1.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 30; Tobacco smoking onset year: 1975; Tobacco smoking quit year: 2005.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B391-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen.
- Sample CUPP-B391-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B391-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 6; Percent stromal cells: 19; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 8; Percent neutrophil infiltration: 3.
